Somatic mutation profile of tumor specimen TCGA-27-1835-01A (aliquot TCGA-27-1835-01A-01D-1494-08) from TCGA case TCGA-27-1835, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.2 years (19,444 days).
Specimen TCGA-27-1835-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 382f1e40-c11b-4783-8e5b-869787a530e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-1835-10A (Blood Derived Normal), aliquot TCGA-27-1835-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66b08835-b79f-480b-a475-1f0d23d01217

The open-access MAF lists 74 somatic variants for this specimen: 59 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 14, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, Splice Region 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRT | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 85/267 reads (32%) | hotspot (GDC flag); catalogued as COSV61965733, COSV62024591; called by muse, mutect2, varscan2
- TP53 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 29/39 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882025, CM159291, CX952222, COSV52671096, COSV52751864, COSV53384298; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTL7B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs139165156; called by muse, varscan2
- ADAMTS19 | c.1690C>G p.L564V | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as rs571424490, COSV50808221; called by muse, mutect2, varscan2
- ADGRF5 | c.3526G>A p.A1176T | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs573068708, COSV51941787; called by muse, mutect2, varscan2
- ADGRV1 | c.6290G>A p.R2097H | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs572910896, COSV67996966; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANGPT4 | c.1018G>A p.V340M | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.193); catalogued as rs746445808, COSV67921665; called by muse, mutect2, varscan2
- CAPN13 | c.1678C>A p.Q560K | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV54436348; called by muse, mutect2, varscan2
- CARMIL2 | c.2039C>T p.A680V | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs762985823, COSV58033055; called by muse, mutect2, varscan2
- CD28 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 70/144 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1023502670, COSV60730032, COSV60730050; called by muse, mutect2, varscan2
- COL4A6 | c.4072+1G>T p.X1358_splice | Splice Site (SNP) | VAF 99/300 reads (33%) | catalogued as COSV57880883; called by muse, mutect2, varscan2
- COL5A1 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 81/237 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.232); catalogued as rs148548209, COSV65669151; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EBF2 | c.571C>A p.L191I | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.308); catalogued as COSV68777879, COSV68780927; called by muse, mutect2, varscan2
- EIF1AX | c.429C>T p.D143= | Splice Region (SNP) | VAF 45/126 reads (36%) | catalogued as rs768926880, COSV65451695; called by muse, mutect2, varscan2
- FAM193A | c.1899_1900del p.F633Lfs*12 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as COSV61199585; called by mutect2, pindel, varscan2
- FBXW10 | c.2857A>C p.M953L | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); catalogued as COSV57061194, COSV57061280; called by muse, varscan2
- GABRA6 | c.440C>A p.T147N | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV50898342; called by muse, mutect2, varscan2
- GCNA | c.1672A>G p.S558G | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as rs765633095, COSV65468564; called by muse, mutect2, varscan2
- HOXA6 | c.427A>C p.M143L | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV56075231; called by muse, mutect2, varscan2
- IFITM1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 111/248 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.179); catalogued as rs1009186817, COSV60250158; called by muse, mutect2, varscan2
- IFT172 | c.4449G>T p.R1483S | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV53140637; called by muse, mutect2, varscan2
- LAMA5 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs754145632, COSV53374416; called by muse, mutect2, varscan2
- LAMB3 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs762942741, COSV61920286; called by muse, mutect2, varscan2
- LETM1 | c.1744-1G>A p.X582_splice | Splice Site (SNP) | VAF 941/1130 reads (83%) | catalogued as COSV57104940; called by muse, mutect2
- LTBP2 | c.2462G>C p.G821A | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.8); PolyPhen benign (0.039); catalogued as COSV56210378, COSV56215048; called by muse, varscan2
- MAP3K21 | c.2278C>T p.R760* | Nonsense Mutation (SNP) | VAF 43/119 reads (36%) | catalogued as rs373332852, COSV64041911; called by muse, mutect2
- MAP3K7 | c.194T>C p.I65T | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65236030; called by muse, mutect2, varscan2
- MATN4 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | PolyPhen probably damaging (0.999); catalogued as rs780190895, COSV59212889; called by muse, mutect2, varscan2
- MDN1 | c.15816del p.I5273Sfs*6 | Frame Shift Del (DEL) | VAF 120/380 reads (32%) | catalogued as COSV65519981, COSV65531824; called by mutect2, pindel, varscan2
- MIOX | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs140377157; called by muse, mutect2, varscan2
- MMP9 | c.1192G>A p.V398M | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171543612, COSV63434587; called by muse, mutect2, varscan2
- NUP210L | c.831G>T p.M277I | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55159377; called by muse, mutect2, varscan2
- OR10G7 | c.245C>T p.T82I | Missense Mutation (SNP) | VAF 93/370 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.347); catalogued as COSV57866101; called by muse, mutect2, varscan2
- OR2M4 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV60707689; called by muse, mutect2, varscan2
- OR5J2 | c.143T>A p.L48* | Nonsense Mutation (SNP) | VAF 161/403 reads (40%) | catalogued as COSV56623676; called by muse, mutect2, varscan2
- PALM | c.1003G>A p.A335T | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.5); PolyPhen benign (0.345); catalogued as rs868588799, COSV52766698; called by muse, mutect2, varscan2
- PIK3CG | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs766854286, COSV63245615; called by muse, mutect2, varscan2
- PLEKHO1 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as rs781922261, COSV50311754; called by muse, mutect2, varscan2
- PLXDC1 | c.399G>A p.S133= | Splice Region (SNP) | VAF 11/31 reads (35%) | catalogued as rs755210443, COSV59550933; called by muse, mutect2, varscan2
- POLA2 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV55486812; called by muse, mutect2, varscan2
- RFX6 | c.1447C>A p.Q483K | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.132); catalogued as rs144863251, COSV60587931; called by muse, mutect2, varscan2
- RMDN2 | c.718T>C p.Y240H (on ENST00000354545 / NM_001322212.2; = p.Y418H on NM_144713.5) | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as COSV52230424; called by muse, mutect2, varscan2
- RPRM | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV57989298; called by muse, varscan2
- RPS4X | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV60182137; called by muse, mutect2, varscan2
- RSPH4A | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 27/83 reads (33%) | catalogued as COSV57637057; called by muse, mutect2, varscan2
- SCN4A | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs766975288, COSV71129589; called by muse, mutect2, varscan2
- SIPA1L2 | c.2011A>G p.T671A | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV53401514; called by muse, mutect2, varscan2
- SLK | c.451A>G p.I151V | Missense Mutation (SNP) | VAF 54/71 reads (76%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as COSV59829615; called by muse, mutect2, varscan2
- SNRK | c.787A>C p.I263L | Missense Mutation (SNP) | VAF 139/360 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV56071457; called by muse, mutect2, varscan2
- SPTA1 | c.2859C>G p.D953E | Missense Mutation (SNP) | VAF 113/313 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV63752879, COSV63754237; called by muse, mutect2, varscan2
- SPTA1 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1184282319, COSV63750644; called by muse, mutect2, varscan2
- STAT4 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.078); catalogued as rs750095435, COSV61832903; called by muse, mutect2, varscan2
- STON2 | c.1155C>G p.I385M (on ENST00000649389 / NM_001366849.2; = p.I328M on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50857769; called by muse, mutect2, varscan2
- TCHH | c.2005G>C p.E669Q | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs755360885; called by muse, varscan2
- TMEM251 | c.37T>A p.S13T | Missense Mutation (SNP) | VAF 102/258 reads (40%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.017); catalogued as COSV52094023; called by muse, mutect2, varscan2
- IGHV3-38 | c.323C>T p.T108M | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- KIR2DL4 | c.542T>A p.V181E (on ENST00000396284; = p.V142E on NM_001080770.2) | Missense Mutation (SNP) | VAF 18/338 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRDM5 | c.962_965del p.D321Vfs*5 | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | called by mutect2, pindel, varscan2
- TMC1 | c.2012dup p.N671Kfs*2 | Frame Shift Ins (INS) | VAF 74/264 reads (28%) | called by mutect2, pindel, varscan2
- C3AR1 | c.918C>T p.Y306= | Silent (SNP) | VAF 68/146 reads (47%) | catalogued as rs758204041, COSV50826036; called by muse, mutect2, varscan2
- DLL1 | c.25C>T p.L9= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as rs757868082, COSV64539047; called by muse, mutect2, varscan2
- HECTD4 | c.10020C>T p.S3340= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV66401340; called by mutect2, varscan2
- MAGEC2 | c.183G>A p.L61= | Silent (SNP) | VAF 75/161 reads (47%) | catalogued as COSV56001886, COSV99909353; called by muse, mutect2, varscan2
- MATN4 | c.1317T>A p.P439= (on ENST00000372754; = p.P398= on NM_003833.4) | Silent (SNP) | VAF 23/71 reads (32%) | catalogued as COSV61353454; called by muse, mutect2, varscan2
- MCM7 | c.1296G>A p.G432= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as rs1345469589, COSV57999513; called by muse, mutect2, varscan2
- MUC17 | c.7149C>T p.D2383= | Silent (SNP) | VAF 165/614 reads (27%) | catalogued as rs138267850, COSV100075844, COSV60305969; called by muse, mutect2, varscan2
- NME8 | c.486G>C p.P162= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV52249073, COSV52256478; called by muse, mutect2, varscan2
- NSD2 | c.3798C>A p.S1266= | Silent (SNP) | VAF 108/123 reads (88%) | catalogued as COSV56397839; called by muse, mutect2, varscan2
- PRR27 | c.330G>A p.P110= | Silent (SNP) | VAF 183/441 reads (41%) | catalogued as rs759437234, COSV60640700; called by muse, mutect2, varscan2
- SLC16A10 | c.915T>C p.F305= | Silent (SNP) | VAF 130/283 reads (46%) | catalogued as COSV64356000; called by muse, mutect2, varscan2
- SULT1C4 | c.555A>T p.G185= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV55599229, COSV99731721; called by muse, mutect2, varscan2
- USP46 | c.876G>C p.L292= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV71513214; called by muse, mutect2, varscan2
- ZNF674 | c.1539C>A p.I513= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV70378648, COSV70379887; called by muse, mutect2, varscan2
- MUC2 | c.*56C>T | 3'UTR (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
